Somatic mutation profile of tumor specimen 0DOV9I from CCDI case PBCCLV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 12.4 years (4,546 days).
Specimen 0DOV9I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0e01aac-6e23-4cfa-b55e-160a35d4f43e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOV8I (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3bf39f6d-8fc8-447c-93d8-00f8d979e945

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COMT | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 148/477 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs778219405; called by muse, varscan2
- MYH14 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 250/722 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs755662126; called by muse, varscan2
- S100A3 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 91/510 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as rs762900643; called by muse, varscan2
- GAK | c.1553C>T p.A518V | Missense Mutation (SNP) | VAF 104/278 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- P2RY8 | c.7G>A p.V3I | Missense Mutation (SNP) | VAF 124/352 reads (35%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, varscan2
- ULBP1 | c.608A>G p.Q203R | Missense Mutation (SNP) | VAF 59/389 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.017); called by muse, varscan2
